Somatic mutation profile of tumor specimen C3N-01874-01 (aliquot CPT0117300006) from CPTAC case C3N-01874, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 84.8 years (30,958 days).
Specimen C3N-01874-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e66c16-c215-41df-95f2-ad31e21d5ba6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01874-31 (Blood Derived Normal), aliquot CPT0117360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80cc0c6b-a3fc-4ed2-8d0a-6e95d2f8e3f2

The open-access MAF lists 76 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Intron 8, Frame Shift Ins 3, Nonsense Mutation 2, 3'UTR 2, RNA 2, 3'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 194/448 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- LDLR | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 163/354 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.443); catalogued as rs557344672, CM012620, CM150269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 141/371 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 115/270 reads (43%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, varscan2
- ADGRE3 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 254/619 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1258750065; called by muse, mutect2, varscan2
- ARID1A | c.4960A>T p.K1654* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100253293; called by mutect2, varscan2
- B4GALNT2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs779668398; called by muse, mutect2, varscan2
- COL6A2 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs771658013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292621126, COSV53743121; called by muse, mutect2, varscan2
- DNAH17 | c.9557C>T p.A3186V | Missense Mutation (SNP) | VAF 245/529 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747233018, COSV67750093; called by muse, mutect2, varscan2
- FRG2C | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 90/795 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1386638927; called by muse, mutect2, varscan2
- IGHV4-39 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 217/235 reads (92%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs374569005; called by muse, mutect2, varscan2
- LRATD1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1016426961; called by muse, mutect2, varscan2
- LSM7 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779214660; called by muse, mutect2, varscan2
- MAP9 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs747141635; called by muse, mutect2, varscan2
- MIGA2 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs767526015, COSV99477421; called by muse, mutect2, varscan2
- MVP | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 217/466 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753938190, COSV62423857; called by muse, mutect2, varscan2
- NEK5 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 143/370 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768928309; called by muse, mutect2, varscan2
- NOL4 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52351743; called by muse, varscan2
- NRXN2 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs766433931, COSV55458552; called by muse, mutect2, varscan2
- NTSR1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as rs766492157; called by muse, mutect2, varscan2
- PCDHA3 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 410/895 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63539756; called by muse, mutect2, varscan2
- PCDHB4 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 460/1029 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as COSV99522076; called by muse, varscan2
- RBFOX1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776698363, COSV60952220; called by muse, mutect2, varscan2
- SALL1 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 157/173 reads (91%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs760334541, COSV51753671; called by muse, mutect2, varscan2
- SLC5A11 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764495479, COSV61740375; called by muse, mutect2, varscan2
- SLC8A3 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 142/323 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761573007; called by muse, mutect2, varscan2
- VPS13C | c.1201C>T p.H401Y (on ENST00000644861 / NM_020821.3; = p.H358Y on NM_017684.5) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275372912; called by muse, mutect2, varscan2
- ADGRE2 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 56/842 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- ADGRG2 | c.572T>C p.I191T (on ENST00000379869 / NM_001079858.3; = p.I188T on NM_005756.4) | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ARID1A | c.4081dup p.M1361Nfs*84 | Frame Shift Ins (INS) | VAF 56/150 reads (37%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CMTR2 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CUBN | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- HNRNPH3 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ILF3 | c.4-5C>T | Splice Region (SNP) | VAF 98/208 reads (47%) | called by muse, mutect2, varscan2
- INTS9 | c.1756_1757dup p.S586Rfs*79 | Frame Shift Ins (INS) | VAF 83/222 reads (37%) | called by mutect2, pindel, varscan2
- ITIH2 | c.2725G>C p.V909L | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- KANSL1 | c.1419dup p.R474Tfs*3 | Frame Shift Ins (INS) | VAF 50/148 reads (34%) | called by mutect2, pindel
- KIF22 | c.1891G>C p.V631L | Missense Mutation (SNP) | VAF 137/275 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- MRC2 | c.2642G>T p.R881L | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- NOMO1 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PLCE1 | c.5431C>G p.L1811V | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBAK | c.1976T>C p.V659A | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SCYL2 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, varscan2
- SKOR2 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.691); called by muse, varscan2
- TBC1D25 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 186/427 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRRAP | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 170/348 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNHIT2 | c.262_268del p.S88Rfs*25 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | called by mutect2, pindel, varscan2
- ZP3 | c.1031C>G p.S344C (on ENST00000394857 / NM_001110354.2; = p.S293C on NM_007155.6) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ASB18 | c.909C>T p.H303= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as rs1259350842; called by muse, mutect2, varscan2
- BEND4 | c.1296C>T p.C432= | Silent (SNP) | VAF 128/304 reads (42%) | catalogued as rs1441571994, COSV72469108; called by muse, mutect2, varscan2
- BUB3 | c.483G>T p.V161= | Silent (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- CTBP2 | c.525G>A p.A175= | Silent (SNP) | VAF 174/350 reads (50%) | catalogued as rs777985668; called by muse, mutect2, varscan2
- FGFRL1 | c.1113G>A p.S371= | Silent (SNP) | VAF 81/161 reads (50%) | catalogued as rs752771234; called by muse, mutect2, varscan2
- GEMIN5 | c.1938G>A p.A646= | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as rs369052797; called by muse, mutect2, varscan2
- GRM4 | c.102C>A p.P34= | Silent (SNP) | VAF 66/160 reads (41%) | called by muse, mutect2, varscan2
- NR0B1 | c.177C>T p.N59= | Silent (SNP) | VAF 124/291 reads (43%) | catalogued as COSV100973573; called by muse, mutect2, varscan2
- OR13A1 | c.591C>T p.C197= | Silent (SNP) | VAF 113/249 reads (45%) | catalogued as rs147583204; called by muse, mutect2, varscan2
- RAPGEF1 | c.2070G>A p.P690= | Silent (SNP) | VAF 103/263 reads (39%) | catalogued as rs376059393; called by muse, mutect2, varscan2
- SLC29A3 | c.1152C>T p.L384= | Silent (SNP) | VAF 79/196 reads (40%) | catalogued as COSV64385755; called by muse, mutect2, varscan2
- SRMS | c.1321C>A p.R441= | Silent (SNP) | VAF 164/359 reads (46%) | catalogued as rs376080206; called by muse, mutect2, varscan2
- TOR3A | c.489G>A p.L163= | Silent (SNP) | VAF 240/739 reads (32%) | catalogued as rs1167679513; called by muse, mutect2, varscan2
- DTX2 | c.1151-72C>T | Intron (SNP) | VAF 464/510 reads (91%) | called by muse, varscan2
- FAM229A | c.*36C>T | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
- FOXP2 | c.1267-1583G>A | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as rs747729448; called by muse, mutect2, varscan2
- GNG7 | c.-78+3266G>A | Intron (SNP) | VAF 256/522 reads (49%) | catalogued as rs1277552822; called by mutect2, varscan2
- KRT17P1 | n.686C>T | RNA (SNP) | VAF 125/489 reads (26%) | catalogued as rs749568425; called by muse, mutect2, varscan2
- LAMP2 | c.*2814G>C | 3'UTR (SNP) | VAF 50/102 reads (49%) | called by muse, mutect2, varscan2
- MPST | c.595+258C>T | Intron (SNP) | VAF 70/150 reads (47%) | called by mutect2, varscan2
- NRK | c.4354-917C>T | Intron (SNP) | VAF 84/160 reads (53%) | catalogued as rs1257874568; called by muse, mutect2, varscan2
- OR5AK4P | n.510T>C | RNA (SNP) | VAF 89/184 reads (48%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948670 C>T | 3'Flank (SNP) | VAF 147/444 reads (33%) | catalogued as rs3175151; called by mutect2, varscan2
- SLC41A3 | c.274-5354C>G | Intron (SNP) | VAF 91/195 reads (47%) | catalogued as COSV59989109; called by muse, mutect2, varscan2
- STX18 | c.237-2455A>G | Intron (SNP) | VAF 82/182 reads (45%) | called by muse, mutect2, varscan2
- WDR25 | c.1413+51T>A | Intron (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
